Somatic mutation profile of tumor specimen 0DIR2J from CCDI case PBBVAT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Myxofibrosarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 6.0 years (2,204 days).
Specimen 0DIR2J: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec6a9e48-12f3-4c28-ab6b-78d39b6bf088.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIQZM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/423eb7aa-9221-4783-8847-001b0260a849

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2832_2836del p.R945Mfs*16 | Frame Shift Del (DEL) | VAF 89/483 reads (18%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 16/653 reads (2%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- NUDCD2 | c.69G>C p.Q23H | Missense Mutation (SNP) | VAF 65/519 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CATSPERG | c.2356+64G>T | Intron (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
